Gene-level copy-number profile of tumor specimen HTMCP-01-15-00367-01A from CGCI case HTMCP-01-15-00367, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 49.6 years (18,120 days).
Specimen HTMCP-01-15-00367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c9ef2a2-935a-4837-99c0-2ec84c4273cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-15-00367-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/222279c0-c7e8-4729-a115-136f831d85a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 2,608; copy number 2: 53,648; copy number 3: 2,122; copy number 4: 6; copy number 6: 3; copy number 7: 3; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 6: CR383658.1.
- chr14:18,418,775–18,596,310, 3 genes, copy number 6–7 (within-gene range 2–7): BNIP3P6, CR383656.10, CR383656.7.
- chr14:18,588,274–18,588,315, 1 gene, copy number 7: CR383656.9.
- chr21:43,107,942–43,168,646, 2 genes, copy number 6–8 (within-gene range 2–8): AP001631.2, MRPL51P2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 8: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
